Somatic mutation profile of tumor specimen TARGET-10-PATHRF-09A (aliquot TARGET-10-PATHRF-09A-01D) from TARGET case TARGET-10-PATHRF, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 5.2 years (1,889 days).
Specimen TARGET-10-PATHRF-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9eceaf3a-2b63-4747-8277-887af76f54b7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PATHRF-10A (Blood Derived Normal), aliquot TARGET-10-PATHRF-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8c6179db-2e9c-4104-9ae8-9e3179d52e61

The open-access MAF lists 16 somatic variants for this specimen: 8 protein-altering or splice-affecting, 5 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, Silent 5, Splice Region 1, Frame Shift Del 1, Frame Shift Ins 1, 5'Flank 1, Intron 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CELA2B | c.469G>A p.V157I | Missense Mutation (SNP) | VAF 19/88 reads (22%) | SIFT tolerated (0.75); PolyPhen benign (0.289); catalogued as COSV65545555; called by muse, mutect2, varscan2
- DGKZ | c.1344_1345insC p.K449Qfs*17 (on ENST00000454345 / NM_001105540.2; = p.K261Qfs*17 on NM_003646.4) | Frame Shift Ins (INS) | VAF 59/139 reads (42%) | catalogued as COSV58984107, COSV58987748; called by mutect2, pindel, varscan2
- LAMA5 | c.5987G>A p.R1996H | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs371782670, COSV53358591; called by muse, mutect2, varscan2
- NOTCH1 | c.7541_7542del p.P2514Rfs*4 | Frame Shift Del (DEL) | VAF 21/66 reads (32%) | catalogued as rs763016003, COSV53024776; ClinVar: uncertain significance; called by mutect2, pindel, varscan2
- NOTCH1 | c.4793G>C p.R1598P | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.918); catalogued as COSV53027279, COSV53097635; called by muse, mutect2, varscan2
- KMT2D | c.4199G>A p.C1400Y | Missense Mutation (SNP) | VAF 7/113 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- PSMD5 | c.703G>A p.A235T | Missense Mutation (SNP) | VAF 6/90 reads (7%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.974); called by muse, mutect2
- ZNF148 | c.-150A>G | Splice Region (SNP) | VAF 69/127 reads (54%) | called by muse, mutect2, varscan2
- NOTCH1 | c.4794C>T p.R1598= | Silent (SNP) | VAF 10/63 reads (16%) | catalogued as rs558708604, COSV53027816, COSV53068513; ClinVar: likely benign; called by muse, mutect2, varscan2
- PLCD1 | c.2166C>A p.P722= | Silent (SNP) | VAF 7/72 reads (10%) | catalogued as COSV52187641; called by muse, mutect2, varscan2
- ZNF219 | c.2157G>C p.G719= | Silent (SNP) | VAF 5/29 reads (17%) | catalogued as COSV53883789; called by muse, mutect2, varscan2
- ZNF347 | c.2445G>A p.G815= | Silent (SNP) | VAF 70/146 reads (48%) | called by muse, mutect2, varscan2
- ZNF469 | c.6006C>T p.T2002= (on ENST00000437464; = p.T2030= on NM_001367624.2) | Silent (SNP) | VAF 59/117 reads (50%) | catalogued as rs754253956; ClinVar: likely benign; called by muse, mutect2, varscan2
- GAS8 | c.756+186T>C | Intron (SNP) | VAF 4/39 reads (10%) | called by mutect2, varscan2
- HCFC1R1 | chr16:3024019 G>A | 5'Flank (SNP) | VAF 14/23 reads (61%) | called by muse, mutect2, varscan2
- ZNF586 | c.-75C>T | 5'UTR (SNP) | VAF 42/112 reads (38%) | catalogued as rs1332859685; called by muse, mutect2, varscan2
